CCDI case PBBNPB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Lymph nodes.
https://portal.gdc.cancer.gov/cases/96b90db4-79de-4a95-9061-f966e51b1ff0

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Lymph nodes of inguinal region or leg; Age at diagnosis: 14.9 years (5,438 days).

Biospecimens (3 samples)
- Sample 0DDEQ5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DDEQB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DDEQF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
